Somatic mutation profile of tumor specimen 0DEA0Q from CCDI case PBBPPC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.7 years (4,656 days).
Specimen 0DEA0Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7c894c-1caa-478e-b9ce-2b22b0194069.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEA0N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eec5e84-37d3-4b02-9b74-dcd30addc43c

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 1, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLAD1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766627769, COSV52700562; called by muse, mutect2, varscan2
- INPP5J | c.2329C>T p.R777W (on ENST00000331075 / NM_001284285.2; = p.R409W on NM_001002837.2) | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766488330; called by muse, mutect2, varscan2
- TPTE2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 146/830 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs769652776; called by muse, mutect2, varscan2
- BCOR | c.4204G>T p.E1402* (on ENST00000378444 / NM_001123385.2; = p.E1368* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 119/287 reads (41%) | called by muse, mutect2, varscan2
- BHLHE22 | c.369_390del p.A124Kfs*34 | Frame Shift Del (DEL) | VAF 68/257 reads (26%) | called by mutect2, varscan2
- CLSPN | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 222/731 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MYBPH | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 154/1145 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TMPRSS9 | c.1211T>A p.M404K (on ENST00000648592; = p.M370K on NM_182973.2) | Missense Mutation (SNP) | VAF 157/510 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TPM3 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 480/1079 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCK | c.627G>A p.T209= | Silent (SNP) | VAF 122/671 reads (18%) | catalogued as rs779762447; called by muse, mutect2, varscan2
- INSC | c.189G>A p.P63= | Silent (SNP) | VAF 83/541 reads (15%) | catalogued as rs371682185, COSV101088941; called by muse, mutect2, varscan2
- NOTCH4 | c.2349G>T p.V783= | Silent (SNP) | VAF 110/778 reads (14%) | called by mutect2, varscan2
- CYFIP1 | c.1675-214G>A | Intron (SNP) | VAF 46/345 reads (13%) | catalogued as rs370070516; called by muse, mutect2, varscan2
- ZNF442 | c.-18G>A | 5'UTR (SNP) | VAF 101/797 reads (13%) | catalogued as rs563488087; called by muse, mutect2, varscan2
